CGCI case HTMCP-01-06-00611 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ca6c81ec-bd33-42b1-9d0b-7a1c37532438

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Dead; Days to death: 13 days.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: primary; Age at diagnosis: 68.5 years (25,028 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 13 days; Max tumor bulk site: Cervical lymph nodes.
   Pathology details: Lymph node involved site: Axillary.
   Pathology details: Lymph node involved site: Parotid.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 13 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day -3,311.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day -3,311: Comorbidities: HIV/AIDS.
- Day -3,311: Risk factors: HIV/AIDS.
- Day 0: Nadir CD4 count: 72.
- Day 0: Weight: 69 kg; Height: 170 cm; BMI: 23.9; CD4 count: 234; Haart treatment indicator: Yes; HIV viral load: 0.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-01-06-00611-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-06-00611-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-06-00611-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Tobacco smoking history indicator: 1; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- History of disease: Year of HIV diagnosis: 2007; HIV rna load at diagnosis: 0; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: No Known Extranodal Involvement.
- Primary pathology: Method initial path diagnosis: Biopsy (all types); Lymph nodes examined: No.
- Tests performed: Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: P53 >20%.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD79a.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-06-00611-01A-01D-10409:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-06-00611-01A-01R-10409:
- % tumour top: 90
- % tumour bottom: 90
